Somatic mutation profile of tumor specimen TARGET-10-PARRYW-09A (aliquot TARGET-10-PARRYW-09A-01D) from TARGET case TARGET-10-PARRYW, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 11.9 years (4,347 days).
Specimen TARGET-10-PARRYW-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ef3f58c8-d5c8-4cc4-9071-34b891ff245d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARRYW-10A (Blood Derived Normal), aliquot TARGET-10-PARRYW-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/31ba6eba-9f2c-4613-94cb-89b7f0a8c9d9

The open-access MAF lists 27 somatic variants for this specimen: 20 protein-altering or splice-affecting, 1 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 18, Intron 4, Nonsense Mutation 2, 5'UTR 1, RNA 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 11/50 reads (22%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- BPIFB3 | c.464G>C p.G155A | Missense Mutation (SNP) | VAF 26/72 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV64957479; called by muse, mutect2, varscan2
- CEP170B | c.3695G>A p.R1232H (on ENST00000453495; = p.R1161H on NM_015005.3) | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.099); catalogued as rs778420508, COSV69023601; called by muse, mutect2, varscan2
- DLG2 | c.2041C>T p.R681W | Missense Mutation (SNP) | VAF 26/68 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54681198; called by muse, mutect2, varscan2
- GABRA6 | c.1063C>A p.P355T | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT tolerated (0.22); PolyPhen benign (0.009); catalogued as rs755235727, COSV50878154, COSV50884745; called by muse, mutect2, varscan2
- HELQ | c.2791G>A p.V931I | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT tolerated (0.7); PolyPhen benign (0.001); catalogued as rs748368408; called by muse, mutect2, varscan2
- KCTD15 | c.653G>A p.R218H | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1388792656; called by muse, mutect2, varscan2
- NOC4L | c.322G>A p.G108S | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (0.59); PolyPhen benign (0.007); catalogued as rs932028653, COSV100223300; called by muse, mutect2, varscan2
- NUMBL | c.1667G>A p.R556H | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.001); catalogued as rs772850434; called by muse, mutect2, varscan2
- RPTN | c.2194C>T p.R732* | Nonsense Mutation (SNP) | VAF 22/202 reads (11%) | catalogued as rs377696297; called by muse, mutect2, varscan2
- SPTBN5 | c.8183C>T p.A2728V | Missense Mutation (SNP) | VAF 30/59 reads (51%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.534); catalogued as rs776116445; called by muse, mutect2
- TMPRSS2 | c.973G>A p.G325R | Missense Mutation (SNP) | VAF 33/172 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.114); catalogued as rs781290787, COSV100152363; called by muse, mutect2, varscan2
- TRRAP | c.9406G>A p.E3136K (on ENST00000359863 / NM_001244580.1; = p.E3107K on NM_003496.3) | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV100722648, COSV62849388; called by muse, mutect2, varscan2
- ZNF18 | c.187C>T p.R63W | Missense Mutation (SNP) | VAF 29/79 reads (37%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.661); catalogued as rs183777667, COSV59550647; called by muse, mutect2, varscan2
- ZNF536 | c.3298G>A p.V1100M | Missense Mutation (SNP) | VAF 14/89 reads (16%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs200453890, COSV62825016; called by muse, mutect2, varscan2
- CES3 | c.13G>A p.V5M | Missense Mutation (SNP) | VAF 8/81 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.445); called by muse, mutect2, varscan2
- DDX21 | c.832A>G p.K278E | Missense Mutation (SNP) | VAF 29/116 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- PARP10 | c.2950C>T p.Q984* | Nonsense Mutation (SNP) | VAF 3/22 reads (14%) | called by muse, varscan2
- TAF3 | c.1054A>T p.I352F | Missense Mutation (SNP) | VAF 27/115 reads (23%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- TFCP2L1 | c.1255G>A p.A419T | Missense Mutation (SNP) | VAF 24/78 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.144); called by muse, mutect2, varscan2
- CFAP161 | c.609C>A p.R203= | Silent (SNP) | VAF 5/29 reads (17%) | catalogued as COSV54428612; called by muse, mutect2, varscan2
- C1QTNF7 | c.-108C>T | 5'UTR (SNP) | VAF 6/42 reads (14%) | catalogued as rs1351852401, COSV54852276; called by muse, mutect2, varscan2
- GGCX | c.725+23G>T | Intron (SNP) | VAF 25/76 reads (33%) | called by muse, mutect2, varscan2
- HLA-F-AS1 | n.1399T>A | RNA (SNP) | VAF 8/46 reads (17%) | called by muse, mutect2, varscan2
- MPP1 | c.1150-57_1150-37delinsCACTTTCCTTTTCTTCCTT | Intron (DEL) | VAF 7/50 reads (14%) | called by pindel, varscan2*
- NDUFAF5 | c.779-1985G>A | Intron (SNP) | VAF 7/30 reads (23%) | called by muse, mutect2, varscan2
- PDGFRA | c.2323+23T>C | Intron (SNP) | VAF 18/65 reads (28%) | called by muse, mutect2, varscan2
